TCGA case TCGA-29-1699 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe0e3851-d8cb-4533-9536-b4826cd25f87

Demographics
Sex at birth: female; Race: white; Age at index: 57 years; Vital status: Dead; Days to death: 1,106 days (3.0 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 57.9 years (21,130 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm.

Follow-up (2 entries)
- ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contacts recording only the day: day 16, day 1,106.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-29-1699-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 5.
  Slide TCGA-29-1699-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
- Sample TCGA-29-1699-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Follow-up form: Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,106 days; disease-specific survival: event status not recorded, 1,106 days; progression-free interval: no event (censored), 1,106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1699-01A-01D-0559-01): tumor purity 0.61, ploidy 5.61, whole-genome doublings 2.
